MMRF case MMRF_1952 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/05b5c882-f3df-420b-846c-64e215f080bc

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.6 years (23,951 days); ISS stage: II; Days to last known disease status: 1,062 days (2.9 years); Days to last follow up: 1,062 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 6.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 99.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 71.4 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.08 mmol/L; Albumin 22 g/L; Total Protein 11.6 g/dL; Glucose 4.51 mmol/L.
- Day 99: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 14.1 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.78 mmol/L.
- Day 164 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 12 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.78 mmol/L.
- Day 242 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 10.4 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.19 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.66 mmol/L.
- Day 341 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 8.74 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.41 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Total Protein 6.1 g/dL; Glucose 7.43 mmol/L.
- Day 439 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 8.67 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 6.12 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.
- Day 523 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 8.13 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 3.45 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 575 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 7.99 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.91 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 656 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 9.9 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 768 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 9.41 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.
- Day 859 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 10.1 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.95 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 971 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 10.7 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.09 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 1,062 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 10.8 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.73 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -3: Weight: 66 kg; Height: 174 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1952_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1952_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
